CPTAC case C3L-06081 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/46d91cd2-e013-4734-a625-4a536c1cc394

Demographics
Sex at birth: female; Race: white; Year of birth: 1999; Vital status: Alive; Country of birth: Turkey.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 22.1 years (8,068 days); Year of diagnosis: 2021; Days to last known disease status: 1,426 days (3.9 years); Progression or recurrence: no; Days to last follow up: 1,426 days (3.9 years).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 337 days; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 702 days (1.9 years); Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,049 days (2.9 years); Karnofsky performance status: 100; ECOG performance status: 0.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (5 samples)
- Samples C3L-06081-50, C3L-06081-51, C3L-06081-52 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-06081-54, C3L-06081-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
